Somatic mutation profile of tumor specimen TCGA-PC-A5DM-01A (aliquot TCGA-PC-A5DM-01A-11D-A27P-09) from TCGA case TCGA-PC-A5DM, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 73.1 years (26,699 days).
Specimen TCGA-PC-A5DM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57b3e8e5-99aa-4c70-a9b0-f18f5d9fd593.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PC-A5DM-10A (Blood Derived Normal), aliquot TCGA-PC-A5DM-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37bf8b73-1cc4-48b1-b399-a2872d0e16b4

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Splice Site 4, Nonsense Mutation 1, Translation Start Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs376872449, COSV58133171; called by muse, mutect2, varscan2
- ACTL8 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100958712; called by muse, mutect2, varscan2
- ADCY5 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV71901309; called by muse, mutect2, varscan2
- CACNB1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1210681314, COSV59999528; called by muse, mutect2, varscan2
- CAMTA1 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100351306; called by muse, mutect2, varscan2
- CARNMT1 | c.1206G>T p.L402F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV65193015; called by muse, mutect2, varscan2
- CENPJ | c.3281A>T p.K1094I | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV101121535; called by muse, mutect2, varscan2
- COPRS | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.195); catalogued as COSV99912008; called by muse, mutect2, varscan2
- DNAH9 | c.3437T>C p.V1146A | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1243462273, COSV99306701; called by muse, mutect2
- EDF1 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.555); catalogued as COSV99808157; called by muse, mutect2, varscan2
- GGA2 | c.1007-1G>T p.X336_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as rs760936527, COSV100564770; called by muse, mutect2, varscan2
- HEPACAM2 | c.1270T>C p.S424P (on ENST00000394468 / NM_001039372.4; = p.S412P on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100506643; called by muse, mutect2, varscan2
- HMGXB4 | c.1365T>A p.I455= | Splice Region (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99330171; called by muse, mutect2, varscan2
- KLRG1 | c.374T>A p.F125Y | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99868451; called by muse, mutect2, varscan2
- KPNA2 | c.1397A>C p.E466A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100388819; called by muse, mutect2, varscan2
- LRP1B | c.6074G>A p.R2025H | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs531700545, COSV67195999, COSV67215817; called by muse, mutect2, varscan2
- MAP4K4 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100155303; called by muse, mutect2, varscan2
- MYOC | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99231583; called by muse, mutect2, varscan2
- OR52N1 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100398697; called by muse, mutect2, varscan2
- PCDH11Y | c.2410G>A p.V804M (on ENST00000400457 / NM_032973.2; = p.V793M on NM_032971.3) | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs780974994, COSV53074882; called by muse, mutect2, varscan2
- PER1 | c.512G>A p.C171Y | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100424241, COSV100424667; called by muse, mutect2, varscan2
- PIWIL3 | c.1477T>C p.S493P | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100177793; called by muse, mutect2, varscan2
- RHCE | c.1073+2T>A p.X358_splice | Splice Site (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99604238; called by muse, mutect2, varscan2
- RIPPLY2 | c.175-2A>C p.X59_splice | Splice Site (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100860749; called by muse, mutect2, varscan2
- SLC22A8 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as COSV100267957; called by muse, mutect2, varscan2
- SLC26A6 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.405); catalogued as COSV56574039; called by muse, mutect2, varscan2
- SLC44A5 | c.1666A>T p.R556* | Nonsense Mutation (SNP) | VAF 42/80 reads (53%) | catalogued as COSV100902220; called by muse, mutect2, varscan2
- SLCO1B3 | c.1683-2A>T p.X561_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99681745; called by muse, mutect2, varscan2
- TICRR | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99177031; called by muse, mutect2
- TUBB8 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs559882106, COSV59115129; called by muse, mutect2, varscan2
- UGT2B4 | c.1315A>C p.K439Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100522515; called by muse, mutect2, varscan2
- UGT8 | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV100179277; called by muse, mutect2, varscan2
- ATRX | c.1734_1741del p.T579Sfs*8 | Frame Shift Del (DEL) | VAF 23/26 reads (88%) | called by mutect2, pindel, varscan2
- MFSD13A | c.2_20del p.M1_?7 | Translation Start Site (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ACSM1 | c.135A>T p.V45= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99533183; called by muse, mutect2, varscan2
- CYGB | c.261G>A p.G87= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV99506189; called by muse, mutect2, varscan2
- DACT3 | c.1806C>T p.F602= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as rs1235113533, COSV100340388; called by muse, mutect2, varscan2
- FBH1 | c.1689C>T p.F563= (on ENST00000362091 / NM_178150.3; = p.F614= on NM_032807.4) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1374081216, COSV100758815; called by muse, mutect2, varscan2
- GCNT2 | c.888C>T p.P296= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs367912474, COSV101097534; called by muse, varscan2
- IGLV9-49 | c.105C>T p.A35= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- MAP3K9 | c.2721G>A p.S907= (on ENST00000554752 / NM_001284230.1; = p.S921= on NM_033141.4) | Silent (SNP) | VAF 80/151 reads (53%) | catalogued as rs376198640; called by muse, mutect2, varscan2
- NDUFS2 | c.483C>T p.I161= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV100917497; called by muse, mutect2, varscan2
- POLR3A | c.3867G>A p.L1289= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100965724; called by muse, mutect2, varscan2
